CCDI case PBCJJW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/07b1b253-eaea-43fc-a03d-63f9fe725211

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,513 days).

Biospecimens (3 samples)
- Samples 0DT9N1, 0DT9NR (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT9NE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
